Somatic mutation profile of tumor specimen TCGA-CV-5966-01A (aliquot TCGA-CV-5966-01A-11D-1683-08) from TCGA case TCGA-CV-5966, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.3 years (23,119 days).
Specimen TCGA-CV-5966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e3516c6-3ef1-4792-bb2d-4ad6e2fe38da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5966-10A (Blood Derived Normal), aliquot TCGA-CV-5966-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a223929-5f3f-4c51-8834-47dd8205d38e

The open-access MAF lists 116 somatic variants for this specimen: 86 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Nonsense Mutation 3, Intron 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, RNA 2, Frame Shift Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD10 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV99845149; called by muse, mutect2, varscan2
- ADRA1A | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as rs573286753, COSV52356817; called by muse, mutect2, varscan2
- ALKBH3 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100236547, COSV57023914, COSV57025698; called by muse, mutect2, varscan2
- ARID5B | c.21G>A p.Q7= | Splice Region (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99690306; called by muse, mutect2, varscan2
- ARL13A | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100879047; called by muse, mutect2, varscan2
- ATRNL1 | c.4048A>G p.I1350V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.558); catalogued as COSV100372530; called by muse, mutect2, varscan2
- CASP8 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV51848562, COSV51858129; called by muse, mutect2, varscan2
- CD1E | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100937053; called by muse, mutect2, varscan2
- CDH3 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99868996; called by muse, mutect2, varscan2
- CDKL5 | c.2845G>A p.V949I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774335258, COSV66106447; called by muse, mutect2, varscan2
- CEP44 | c.957T>G p.N319K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99639747; called by muse, mutect2, varscan2
- CFAP251 | c.750C>T p.T250= | Splice Region (SNP) | VAF 3/31 reads (10%) | catalogued as COSV56615868; called by muse, mutect2
- CFTR | c.3950A>C p.K1317T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV99139012; called by muse, mutect2, varscan2
- CHD9 | c.4160C>T p.T1387I | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99529629; called by muse, mutect2
- CHURC1 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV100767480; called by muse, mutect2, varscan2
- CKAP2 | c.1750A>G p.T584A (on ENST00000378037 / NM_001098525.2; = p.T583A on NM_018204.5) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99318439; called by muse, mutect2, varscan2
- COL27A1 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs779610682, COSV100621270; called by muse, mutect2, varscan2
- COL5A1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148548209, COSV65669151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSRP3 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56389324; called by muse, mutect2, varscan2
- DACH1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100499060; called by muse, mutect2
- DCAF13 | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99885600; called by muse, mutect2, varscan2
- DCHS1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV100202493; called by muse, mutect2, varscan2
- DCST1 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV99665236; called by muse, mutect2, varscan2
- DCST2 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99792199; called by muse, mutect2, varscan2
- DLG5 | c.4517A>G p.K1506R | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs755044773, COSV100967809; called by muse, mutect2, varscan2
- DNA2 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100622777; called by muse, mutect2, varscan2
- DNAH10 | c.8779G>A p.A2927T (on ENST00000409039; = p.A2866T on NM_207437.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV69000226; called by muse, mutect2, varscan2
- EMC2 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99624491; called by muse, mutect2, varscan2
- FAM161A | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100281477; called by muse, mutect2, varscan2
- FAM172A | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.799); catalogued as COSV67939343; called by muse, mutect2, varscan2
- FAT1 | c.10830C>G p.Y3610* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101499603; called by muse, mutect2, varscan2
- FGF1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770590235, COSV61803559; called by muse, mutect2, varscan2
- FOCAD | c.4632G>C p.K1544N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.798); catalogued as COSV100620662; called by muse, mutect2
- GON4L | c.2926G>A p.G976S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99675551; called by muse, mutect2, varscan2
- GP5 | c.173T>A p.F58Y | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99757551; called by muse, mutect2, varscan2
- GRID1 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100026085; called by muse, mutect2, varscan2
- H2AC12 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.066); catalogued as COSV63616825; called by muse, mutect2, varscan2
- HERPUD1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100296050; called by muse, mutect2, varscan2
- HIPK3 | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100306015; called by muse, mutect2, varscan2
- IL24 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV99686546; called by muse, mutect2, varscan2
- KCNF1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs755311321, COSV54464682; called by muse, mutect2, varscan2
- KIF3A | c.184A>C p.T62P | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101109485; called by muse, mutect2, varscan2
- MAP7 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100643997; called by muse, mutect2, varscan2
- MCF2 | c.51+2T>A p.X17_splice | Splice Site (SNP) | VAF 36/205 reads (18%) | catalogued as COSV100645045; called by muse, mutect2, varscan2
- MIB1 | c.2084A>T p.Q695L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV99839331; called by muse, mutect2
- MTOR | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100816608; called by muse, mutect2, varscan2
- MYCBP2 | c.13589A>G p.Y4530C (on ENST00000357337; = p.Y4568C on NM_015057.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100631537; called by muse, mutect2, varscan2
- MYCBP2 | c.8432A>G p.N2811S (on ENST00000357337; = p.N2849S on NM_015057.5) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62031651; called by muse, mutect2, varscan2
- NPY | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54214956; called by muse, mutect2, varscan2
- NUDT12 | c.450T>A p.F150L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100048316; called by muse, mutect2, varscan2
- PCDHA4 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as COSV100793425, COSV63540934; called by muse, mutect2, varscan2
- PCDHB15 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99179153; called by muse, mutect2, varscan2
- PCDHB8 | c.1293G>C p.R431S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.396); catalogued as COSV99177263, COSV99177287; called by muse, mutect2, varscan2
- PCLO | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100433683, COSV100436756; called by muse, mutect2, varscan2
- PEAK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as rs759962548, COSV100457430; called by muse, varscan2
- PEX11G | c.178A>T p.R60W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675913; called by muse, mutect2, varscan2
- PKP4 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs750033852, COSV101081474; called by muse, mutect2, varscan2
- PRAMEF17 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV101068785; called by muse, mutect2, varscan2
- PSME3IP1 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100483755; called by muse, mutect2, varscan2
- ROS1 | c.2708T>G p.I903S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as COSV100877632; called by muse, mutect2, varscan2
- SHROOM3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99935139; called by muse, mutect2, varscan2
- SLC47A2 | c.1203-1G>C p.X401_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as rs750175660, COSV100328219; called by muse, mutect2, varscan2
- SMTN | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100294855; called by muse, mutect2, varscan2
- SPRY2 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV101001740; called by muse, mutect2, varscan2
- SYNE1 | c.9418G>A p.A3140T (on ENST00000367255 / NM_182961.4; = p.A3147T on NM_033071.3) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99575901; called by muse, mutect2, varscan2
- TCERG1 | c.2280C>G p.F760L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1336405469, COSV99695193; called by muse, mutect2, varscan2
- TFEB | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100026426; called by muse, mutect2, varscan2
- THSD7A | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs765745304, COSV101448644, COSV70264999; called by muse, mutect2, varscan2
- TKTL2 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV54919560, COSV99761686; called by muse, mutect2, varscan2
- TPST2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs763253761, COSV100114224; called by muse, mutect2, varscan2
- TTC39B | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99895972; called by muse, mutect2, varscan2
- UGDH | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100328575, COSV57099727; called by muse, mutect2, varscan2
- USP31 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291585076, COSV99565741; called by muse, mutect2, varscan2
- VARS1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.173); catalogued as COSV100791849; called by muse, mutect2, varscan2
- VCAN | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54112704, COSV99427054; called by mutect2, varscan2
- WDR18 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs761796670, COSV52123097; called by mutect2, varscan2
- ZCCHC12 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.109); catalogued as COSV100038638; called by muse, mutect2, varscan2
- ZNF107 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV100788487, COSV61326763; called by muse, mutect2, varscan2
- ZNF320 | c.711A>T p.R237S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV101206922; called by muse, mutect2, varscan2
- ZNF527 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100648770; called by muse, mutect2, varscan2
- ZSWIM3 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as rs754132693, COSV99666910; called by muse, mutect2, varscan2
- DGCR6L | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, varscan2
- NOTCH1 | c.1901_1902dup p.G635Qfs*138 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- PURB | c.143dup p.L48Ffs*53 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- RABGGTB | c.278del p.P93Lfs*24 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.3906A>G p.R1302= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV100041968; called by muse, mutect2, varscan2
- ARHGEF11 | c.1530G>A p.P510= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs761026325, COSV63810389; called by muse, mutect2, varscan2
- ATP10B | c.1116C>A p.I372= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV58782315; called by muse, mutect2, varscan2
- CADM2 | c.1107C>T p.L369= (on ENST00000407528 / NM_001167674.2; = p.L371= on NM_153184.4) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs768991590, COSV101058952; called by muse, mutect2, varscan2
- CYC1 | c.246G>C p.V82= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs538272583, COSV59645060; called by muse, mutect2, varscan2
- DENND2B | c.2508G>A p.S836= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs771320140, COSV58207797; called by muse, mutect2, varscan2
- DLX1 | c.327G>A p.E109= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs371818895; called by muse, mutect2, varscan2
- EVI5L | c.783C>T p.F261= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV99563483; called by muse, mutect2, varscan2
- IRS4 | c.513C>T p.F171= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs759750511, COSV100929682; called by muse, mutect2, varscan2
- ITGA7 | c.1527C>T p.T509= (on ENST00000555728; = p.T465= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs199722672; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP10-6 | c.786C>A p.T262= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV100555226; called by muse, mutect2, varscan2
- LRRK2 | c.5298A>T p.T1766= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100110998; called by muse, mutect2, varscan2
- NFXL1 | c.1278C>T p.I426= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100216995; called by muse, mutect2
- NUMA1 | c.5502G>A p.S1834= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs763350835, COSV52620379; called by muse, mutect2
- OR4N5 | c.436T>C p.L146= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV100374206; called by muse, mutect2
- OR6B2 | c.285C>A p.V95= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs368904252, COSV99401706; called by muse, mutect2, varscan2
- PJA1 | c.1251T>G p.P417= (on ENST00000361478 / NM_145119.4; = p.P229= on NM_022368.5) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100824793; called by muse, mutect2, varscan2
- PLOD3 | c.180G>A p.E60= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99778250; called by muse, mutect2, varscan2
- PRDM10 | c.132C>T p.R44= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as COSV100702164, COSV62603471; called by muse, mutect2, varscan2
- RAP1GAP2 | c.381G>C p.G127= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54585979, COSV99624196; called by muse, mutect2, varscan2
- SERINC1 | c.330A>G p.K110= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100305349; called by muse, mutect2, varscan2
- SLC66A1 | c.774C>T p.G258= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs752709168, COSV100913322; called by muse, mutect2, varscan2
- UPP1 | c.672C>G p.L224= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100080873; called by muse, mutect2, varscan2
- FOXP1 | c.180+178G>A | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100562271; called by muse, mutect2, varscan2
- GSPT1 | c.-63+144C>T | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as rs1188159880; called by muse, mutect2
- MFSD4B | c.*247G>A | 3'UTR (SNP) | VAF 13/48 reads (27%) | catalogued as rs1245109361, COSV100920608; called by muse, mutect2, varscan2
- MIR891B | n.51G>A | RNA (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- SON | c.6657+237G>A | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99279537; called by muse, mutect2, varscan2
- TAOK2 | chr16:29990788 G>A | 3'Flank (SNP) | VAF 20/77 reads (26%) | catalogued as rs1312346196, COSV99663288; called by muse, mutect2, varscan2
- XIST | n.10195T>C | RNA (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
